Somatic mutation profile of tumor specimen TCGA-NC-A5HE-01A (aliquot TCGA-NC-A5HE-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HE, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.7 years (22,179 days).
Specimen TCGA-NC-A5HE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5259605e-cd3c-4fb5-8b2e-850b5c702805.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HE-10A (Blood Derived Normal), aliquot TCGA-NC-A5HE-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5292c4a9-15ca-4487-a714-e27248520f6c

The open-access MAF lists 218 somatic variants for this specimen: 163 protein-altering or splice-affecting, 52 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 52, Nonsense Mutation 12, Splice Site 6, Intron 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 11/57 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- TP53 | c.373_375+9del p.X125_splice | Splice Site (DEL) | VAF 12/114 reads (11%) | hotspot (GDC flag); called by mutect2, pindel
- ABCA13 | c.8363A>C p.D2788A | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.228); catalogued as COSV101446992; called by muse, mutect2, varscan2
- ABCC9 | c.4127A>C p.D1376A | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99685943; called by muse, mutect2, varscan2
- ACAN | c.4793G>T p.G1598V | Missense Mutation (SNP) | VAF 32/163 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV100718334; called by muse, mutect2, varscan2
- ACVR1B | c.1243C>G p.R415G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1361074077, COSV99231552; called by muse, mutect2, varscan2
- ADAD1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV99635782; called by muse, mutect2, varscan2
- ADAMTS12 | c.4349G>T p.C1450F | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100711126; called by muse, mutect2
- ADAMTS18 | c.1433G>T p.S478I | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51423438, COSV99273163; called by muse, mutect2, varscan2
- ADAMTS4 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917781; called by muse, mutect2, varscan2
- ADAMTSL3 | c.491A>G p.K164R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs779900828, COSV54446924, COSV99719305; called by muse, mutect2, varscan2
- ADGRB3 | c.3646C>A p.L1216I | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99485552; called by muse, mutect2, varscan2
- ALDH1L1 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as COSV99856983; called by muse, mutect2
- ALPP | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV101235157; called by muse, mutect2, varscan2
- ALPP | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV101235158; called by muse, mutect2, varscan2
- ANKRD12 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100041492, COSV50852404; called by muse, mutect2
- APOB | c.3676G>T p.V1226L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs138681343, COSV99266086; called by muse, mutect2, varscan2
- ARHGAP17 | c.2045C>A p.T682K (on ENST00000289968 / NM_001006634.3; = p.T604K on NM_018054.6) | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.03); catalogued as COSV99253587; called by muse, mutect2, varscan2
- BAAT | c.669+1G>A p.X223_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99408534; called by muse, mutect2, varscan2
- C7 | c.1217G>C p.W406S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495953; called by muse, mutect2, varscan2
- C7 | c.1218G>T p.W406C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100495955; called by muse, mutect2, varscan2
- CACNA1S | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100755093; called by muse, mutect2, varscan2
- CACNB2 | c.268G>C p.E90Q (on ENST00000324631 / NM_201596.3; = p.E35Q on NM_000724.4) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99994993, COSV99996381; called by muse, mutect2, varscan2
- CACNG8 | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99555038; called by muse, mutect2
- CADPS2 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV100463425; called by muse, varscan2
- CCDC32 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100785965; called by muse, mutect2, varscan2
- CFAP65 | c.685G>T p.G229W | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99838361; called by muse, mutect2, varscan2
- CFAP91 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99847187; called by muse, mutect2, varscan2
- CHD7 | c.3698G>T p.G1233V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1173391141, COSV101418280; called by muse, mutect2, varscan2
- CNTN4 | c.2945G>A p.S982N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV100639352; called by muse, mutect2
- CNTN5 | c.2411G>T p.G804V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99678016; called by muse, mutect2
- COG1 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 27/154 reads (18%) | catalogued as COSV100245307, COSV100245341; called by muse, mutect2, varscan2
- COLEC12 | c.1558C>G p.Q520E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV101232092; called by muse, varscan2
- CREB3 | c.577C>T p.Q193* | Nonsense Mutation (SNP) | VAF 33/178 reads (19%) | catalogued as COSV59206779; called by muse, mutect2, varscan2
- CSGALNACT2 | c.636A>G p.I212M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV65675624; called by muse, mutect2, varscan2
- CTNNA3 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.587); catalogued as COSV65528570; called by muse, mutect2, varscan2
- CTNND2 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100477717, COSV58912554; called by muse, mutect2, varscan2
- CYP4F22 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs368958384; called by muse, mutect2, varscan2
- DCAF12 | c.144C>G p.Y48* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100778380, COSV100778388; called by muse, mutect2, varscan2
- DCAF4L2 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60482056; called by muse, mutect2, varscan2
- DGKI | c.2207A>G p.Y736C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs141664688, COSV55947352, COSV99935182; called by muse, mutect2, varscan2
- DISP2 | c.4037A>T p.E1346V | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99140099; called by muse, mutect2
- DLC1 | c.4220G>T p.S1407I (on ENST00000276297 / NM_001348081.2; = p.S970I on NM_006094.5) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.625); catalogued as COSV99363608; called by muse, mutect2, varscan2
- DMD | c.4945G>A p.V1649M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs1300066468, COSV100820230; called by muse, mutect2, varscan2
- DNAH8 | c.3389G>T p.R1130L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100545832, COSV59443444; called by muse, mutect2, varscan2
- DST | c.15931G>C p.G5311R (on ENST00000361203 / NM_001374722.1; = p.G2899R on NM_015548.5) | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99757271; called by muse, mutect2, varscan2
- EEFSEC | c.912T>A p.C304* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV99630572; called by muse, mutect2, varscan2
- EFL1 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99187335; called by muse, mutect2, varscan2
- EIF5A2 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1339998540, COSV99858690; called by muse, mutect2, varscan2
- ELOVL4 | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.006); catalogued as COSV100876310; called by muse, mutect2
- ENPP2 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV99308493; called by muse, mutect2, varscan2
- EPB41L4A | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV99813554; called by muse, mutect2, varscan2
- ERCC6 | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV100875974; called by muse, mutect2, varscan2
- FAM160A2 | c.2044G>C p.E682Q (on ENST00000449352 / NM_001098794.2; = p.E696Q on NM_032127.4) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV99792153; called by muse, mutect2, varscan2
- FAT1 | c.13644C>A p.D4548E | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs779949968, COSV101499403; called by muse, mutect2, varscan2
- FCRL4 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54859880, COSV99619955; called by muse, mutect2, varscan2
- FEM1A | c.515A>C p.Q172P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.233); catalogued as COSV99521464; called by muse, mutect2
- FLT4 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as rs368621289; called by muse, mutect2, varscan2
- FPR1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV100494124; called by muse, mutect2
- FXYD7 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.95); catalogued as COSV99544917; called by muse, mutect2, varscan2
- G2E3 | c.1583G>T p.R528I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99249707; called by muse, mutect2, varscan2
- GABRR2 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101298981; called by muse, mutect2
- GADL1 | c.1031T>G p.L344R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV99244526; called by muse, mutect2, varscan2
- GAP43 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs747821934, COSV100525667, COSV100525884; called by muse, mutect2, varscan2
- GDF3 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV100325306; called by muse, mutect2, varscan2
- GLI3 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as rs1349413059, COSV101229909; called by muse, mutect2, varscan2
- GOLIM4 | c.1498C>A p.Q500K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.167); catalogued as COSV100463095; called by muse, mutect2, varscan2
- GPATCH2L | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99833595; called by muse, mutect2, varscan2
- GTPBP10 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.486); catalogued as COSV55989106; called by muse, mutect2
- GUCY1B1 | c.913C>A p.R305S | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1481431741, COSV100025627; called by muse, mutect2
- HSD17B14 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.359); catalogued as rs754586753, COSV54365485, COSV99612688; called by muse, mutect2, varscan2
- IGFN1 | c.3611A>G p.Y1204C (on ENST00000295591 / NM_001367841.1; = p.Y3661C on NM_001164586.2) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99812648; called by muse, mutect2, varscan2
- IL6ST | c.2345C>G p.S782C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410885; called by muse, mutect2, varscan2
- INPP4B | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV99525043; called by muse, mutect2, varscan2
- ITGA7 | c.1046T>C p.L349P (on ENST00000555728; = p.L305P on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99146069; called by muse, mutect2, varscan2
- ITGBL1 | c.1381C>A p.L461I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.125); catalogued as COSV101095464, COSV101095591; called by muse, mutect2
- ITIH5 | c.2401C>A p.Q801K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.386); catalogued as COSV99903574; called by muse, mutect2
- KARS1 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as COSV100094171; called by muse, mutect2, varscan2
- KCNAB2 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99379155; called by muse, mutect2
- KCTD8 | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV100759649; called by muse, mutect2, varscan2
- KDM3B | c.2275A>G p.N759D | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100069797; called by muse, mutect2, varscan2
- KIF21A | c.2967G>T p.M989I (on ENST00000361418 / NM_001378440.1; = p.M976I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100735495; called by muse, mutect2, varscan2
- KLHL32 | c.1838C>A p.P613H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99247125; called by muse, mutect2, varscan2
- KRTAP10-11 | c.483C>A p.C161* | Nonsense Mutation (SNP) | VAF 12/221 reads (5%) | catalogued as COSV100554123; called by muse, mutect2
- LACC1 | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.273); catalogued as COSV100354689; called by muse, mutect2, varscan2
- LAMP3 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99660586; called by muse, mutect2, varscan2
- LCMT2 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99980104; called by muse, mutect2, varscan2
- LCT | c.979A>G p.K327E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99929682; called by muse, mutect2
- LSM11 | c.761C>A p.S254* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV99643980; called by muse, mutect2
- MAN1B1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1464254450, COSV65378007; called by muse, mutect2, varscan2
- MARCHF8 | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100165852; called by muse, mutect2, varscan2
- MC4R | c.416G>T p.S139I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100236008; called by muse, mutect2, varscan2
- MRC2 | c.2278C>A p.R760S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.518); catalogued as COSV100316342, COSV57637436; called by muse, mutect2, varscan2
- MUC16 | c.14882C>T p.S4961F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV101200172; called by muse, mutect2
- NDUFAF5 | c.952C>G p.P318A | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); catalogued as COSV65248057; called by muse, mutect2, varscan2
- NFATC2IP | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100297589; called by muse, mutect2
- NOS1 | c.853-1G>T p.X285_splice | Splice Site (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100500790; called by muse, mutect2, varscan2
- NPHP4 | c.1442G>T p.S481I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV100976977; called by muse, mutect2, varscan2
- NT5C3B | c.735G>T p.Q245H | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV99505228; called by muse, mutect2, varscan2
- NXN | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as COSV100403173; called by muse, mutect2, varscan2
- OBSCN | c.1391G>T p.G464V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV52779120, COSV99479969; called by muse, mutect2, varscan2
- OR2M3 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.098); catalogued as COSV101513447; called by muse, mutect2, varscan2
- OR2M3 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV101513448, COSV71758993; called by muse, mutect2, varscan2
- OR2W3 | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831716; called by muse, mutect2
- OR4A5 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1298398487, COSV100157012, COSV100157146, COSV100157410; called by muse, mutect2, varscan2
- OR4C12 | c.482C>G p.T161R | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV100078506, COSV58860096; called by muse, mutect2, varscan2
- OR4C6 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); catalogued as COSV100051676; called by muse, mutect2, varscan2
- OR4K5 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100262415, COSV60005807; called by muse, mutect2
- OR4L1 | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100235750; called by muse, mutect2, varscan2
- OR5AC2 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 17/133 reads (13%) | catalogued as COSV100684401; called by muse, mutect2, varscan2
- OR5AC2 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100684402; called by muse, mutect2, varscan2
- OR5L2 | c.436T>A p.S146T | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV101004345; called by muse, mutect2, varscan2
- PCDHB15 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.315); catalogued as COSV99178983; called by muse, mutect2, varscan2
- PCDHB15 | c.428C>A p.P143Q | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); catalogued as COSV99178985; called by muse, mutect2
- PCDHB7 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1358732711, COSV50791293, COSV99176156; called by muse, mutect2
- PDZRN4 | c.2689G>T p.G897W (on ENST00000402685 / NM_001164595.2; = p.G639W on NM_013377.4) | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114718, COSV54206067; called by muse, mutect2
- PDZRN4 | c.2690G>T p.G897V (on ENST00000402685 / NM_001164595.2; = p.G639V on NM_013377.4) | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114722; called by muse, mutect2
- PLEKHO2 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | catalogued as COSV100060790; called by muse, mutect2
- PLXNA4 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.339); catalogued as rs746205942, COSV100324842, COSV58150778; called by muse, mutect2
- PRPF4 | c.127G>T p.A43S (on ENST00000374198 / NM_001322267.2; = p.A44S on NM_004697.5) | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100950707; called by muse, mutect2, varscan2
- PRUNE1 | c.1108T>G p.S370A | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1366513886, COSV99639643; called by muse, mutect2, varscan2
- PTPRN2 | c.2598T>A p.N866K | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV101153330, COSV101153402; called by muse, mutect2, varscan2
- RAD50 | c.3751G>C p.E1251Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV54752060, COSV99529087; called by muse, mutect2, varscan2
- RAI1 | c.2107A>G p.T703A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV55390101; called by muse, mutect2, varscan2
- RAPGEF4 | c.2253+1G>A p.X751_splice | Splice Site (SNP) | VAF 11/126 reads (9%) | catalogued as COSV99910818; called by muse, mutect2
- RBM19 | c.2690G>C p.S897T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99926225; called by muse, mutect2, varscan2
- RIMS1 | c.3308G>T p.S1103I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV99327620; called by muse, mutect2, varscan2
- RYR2 | c.3043G>T p.G1015C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63684498; called by muse, mutect2, varscan2
- SEC16B | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100381666; called by muse, mutect2, varscan2
- SLC17A4 | c.769C>A p.H257N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100930612, COSV100930656; called by muse, mutect2, varscan2
- SLC2A3 | c.1277A>G p.Y426C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as rs1420930840, COSV99306707; called by muse, mutect2, varscan2
- SLC35F3 | c.1250C>A p.P417H (on ENST00000366617 / NM_001300845.1; = p.P486H on NM_173508.4) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV100784740, COSV100784798; called by muse, mutect2, varscan2
- SLC9A2 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99296361; called by muse, mutect2, varscan2
- SLITRK3 | c.2627G>T p.G876V | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.972); catalogued as COSV53845814, COSV99578942, COSV99580309; called by muse, mutect2, varscan2
- SPAG16 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99793831; called by muse, mutect2, varscan2
- SPHKAP | c.3912G>T p.M1304I | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100764209; called by muse, mutect2, varscan2
- SUPT3H | c.724C>T p.Q242* (on ENST00000371460 / NM_181356.3; = p.Q231* on NM_003599.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100177386; called by muse, mutect2
- TBC1D21 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100311378; called by muse, mutect2, varscan2
- TGFBR1 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM063199, COSV100895366; called by muse, mutect2, varscan2
- TIAM2 | c.3938G>A p.G1313E | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99265603; called by muse, mutect2
- TIMM17A | c.31T>C p.W11R | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.565); catalogued as COSV100938998; called by muse, mutect2, varscan2
- TINAG | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.399); catalogued as COSV99449819; called by muse, mutect2, varscan2
- TRRAP | c.712-1G>A p.X238_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as COSV100722591; called by muse, mutect2, varscan2
- TTN | c.59195T>C p.L19732S (on ENST00000591111; = p.L12308S on NM_003319.4) | Missense Mutation (SNP) | VAF 65/166 reads (39%) | PolyPhen possibly damaging (0.572); catalogued as rs1435172600, COSV100617473; called by muse, mutect2, varscan2
- UGT2B10 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV99608424; called by muse, mutect2, varscan2
- VIL1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99945612; called by muse, mutect2, varscan2
- VNN1 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs1008433378, COSV63390810; called by muse, mutect2, varscan2
- VNN1 | c.351G>C p.Q117H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100907750; called by muse, mutect2
- XIRP2 | c.7108A>G p.M2370V (on ENST00000628543; = p.M2545V on NM_152381.6) | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs372791859; called by muse, mutect2, varscan2
- YIPF2 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99450141; called by muse, mutect2, varscan2
- ZBED9 | c.1198T>C p.C400R | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as COSV101509280; called by muse, mutect2, varscan2
- ZEB1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100314543; called by muse, mutect2, varscan2
- ZNF527 | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100648742; called by muse, mutect2, varscan2
- ZNF587 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV100299547; called by muse, mutect2, varscan2
- ZNF665 | c.1684A>T p.R562W (on ENST00000600412; = p.R627W on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101128497; called by muse, mutect2, varscan2
- ZNF69 | c.461A>G p.Y154C (on ENST00000429654 / NM_001364730.1; = p.Y140C on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1451115505, COSV100421028; called by muse, mutect2, varscan2
- ZNF721 | c.934A>G p.R312G (on ENST00000338977; = p.R324G on NM_133474.4) | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100167458; called by muse, mutect2, varscan2
- ZNF780B | c.1256G>T p.C419F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99665789; called by muse, mutect2, varscan2
- DENND1B | c.299dup p.Y100* | Nonsense Mutation (INS) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- EPN2 | c.1414_1415del p.E472Ifs*16 | Frame Shift Del (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- GPAT3 | c.916dup p.C306Lfs*11 | Frame Shift Ins (INS) | VAF 3/28 reads (11%) | called by mutect2, pindel
- IGHG1 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM5 | c.1099_1119+10del p.X367_splice | Splice Site (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- ADAMTS12 | c.429C>T p.G143= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100711127; called by muse, mutect2, varscan2
- ANKRD30A | c.1011C>T p.D337= (on ENST00000611781; = p.D281= on NM_052997.2) | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100653698; called by muse, mutect2, varscan2
- ATP13A5 | c.687C>T p.A229= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs772692546, COSV100665268; called by muse, mutect2
- BPI | c.1146C>T p.S382= (on ENST00000262865; = p.S378= on NM_001725.3) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99480719; called by muse, mutect2
- BPIFA2 | c.609G>T p.T203= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs373151340, COSV53610718; called by muse, mutect2, varscan2
- BRINP3 | c.381T>A p.L127= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100818965, COSV66520535; called by muse, mutect2, varscan2
- CNGA2 | c.1170T>C p.D390= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV100323754; called by muse, mutect2, varscan2
- CTNNA2 | c.30G>T p.L10= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100784772, COSV63602666, COSV63603564; called by muse, mutect2, varscan2
- DNAH7 | c.2091G>A p.E697= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100415682; called by muse, mutect2, varscan2
- DST | c.12036A>G p.R4012= (on ENST00000361203 / NM_001374722.1; = p.R1600= on NM_015548.5) | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV99757276; called by muse, mutect2, varscan2
- DYNC1I1 | c.1374C>G p.G458= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as COSV100268596; called by muse, mutect2, varscan2
- ELP2 | c.336G>T p.A112= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs770524620, COSV100626888; called by muse, mutect2, varscan2
- EPRS1 | c.2940A>G p.K980= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100859403; called by muse, mutect2, varscan2
- FASTKD1 | c.933A>G p.V311= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV101328510; called by muse, mutect2, varscan2
- FCGBP | c.10383C>T p.F3461= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs766273578; called by muse, mutect2, varscan2
- FRY | c.426A>T p.S142= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100969393; called by muse, mutect2, varscan2
- GP2 | c.1179G>T p.R393= (on ENST00000381362 / NM_001007240.3; = p.R390= on NM_001502.4) | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV100221522; called by muse, mutect2, varscan2
- GPIHBP1 | c.387C>A p.T129= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as COSV100427373; called by muse, mutect2, varscan2
- HAS1 | c.750C>T p.L250= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as rs201445042, COSV55786953; called by muse, mutect2, varscan2
- HCN1 | c.966G>T p.L322= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100300693; called by muse, mutect2
- HSPA6 | c.1584G>A p.K528= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100554181, COSV99046665; called by muse, mutect2, varscan2
- ITIH5 | c.2400C>A p.I800= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99904904; called by muse, mutect2
- LGSN | c.738C>T p.G246= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101040554; called by muse, mutect2, varscan2
- LRP6 | c.4593C>T p.P1531= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs772094915, COSV99743533; called by muse, mutect2, varscan2
- MMP19 | c.933T>C p.Y311= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100491137; called by muse, mutect2, varscan2
- MMP26 | c.612G>T p.L204= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100332036, COSV56172433; called by muse, mutect2
- MUC16 | c.10539T>A p.A3513= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV101200173; called by muse, mutect2, varscan2
- MUC16 | c.9054C>T p.S3018= | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as rs757421643, COSV101200174; called by muse, mutect2, varscan2
- NOTCH4 | c.618C>T p.P206= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1427709013, COSV100900734; called by muse, mutect2, varscan2
- NRG3 | c.450G>A p.T150= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1372406720, COSV64542433, COSV64576975; called by muse, mutect2, varscan2
- NUTM2F | c.12T>C p.N4= | Silent (SNP) | VAF 21/257 reads (8%) | catalogued as COSV99480188; called by muse, mutect2
- OR51D1 | c.774C>A p.L258= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV62914652, COSV62914667; called by muse, mutect2, varscan2
- OR52N4 | c.207C>T p.S69= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100421692; called by muse, mutect2, varscan2
- PICK1 | c.1140T>C p.D380= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100260164; called by muse, mutect2, varscan2
- PLA2G6 | c.1299C>T p.P433= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1324482461, COSV100140498; called by muse, mutect2, varscan2
- POLR3B | c.2928C>T p.L976= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs754671920, COSV99943515; called by muse, mutect2, varscan2
- PRR12 | c.3505C>T p.L1169= (on ENST00000615927; = p.L1990= on NM_020719.3) | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV101330700; called by muse, mutect2
- RBBP8NL | c.1119C>T p.V373= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99436710; called by muse, mutect2
- RPS16 | c.9C>T p.S3= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs765196033, COSV99261834; called by muse, mutect2
- SF3B4 | c.390C>G p.P130= | Silent (SNP) | VAF 15/105 reads (14%) | catalogued as COSV99641067, COSV99641220; called by muse, mutect2, varscan2
- SLC25A37 | c.732C>T p.A244= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs375263954; called by muse, mutect2, varscan2
- SPTBN2 | c.1563C>T p.A521= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs370685694; ClinVar: likely benign; called by muse, mutect2, varscan2
- STING1 | c.678C>T p.P226= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100423459; called by muse, mutect2, varscan2
- TAS2R5 | c.147G>A p.L49= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV99924812; called by muse, mutect2, varscan2
- TNN | c.1887C>T p.D629= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as COSV99512172; called by muse, mutect2, varscan2
- TRPC6 | c.687C>T p.C229= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100723655; called by muse, mutect2, varscan2
- VANGL1 | c.1542T>C p.F514= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100049232; called by muse, mutect2, varscan2
- XYLT1 | c.1155C>A p.P385= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV54496878; called by muse, mutect2, varscan2
- ZNF521 | c.1581C>A p.S527= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100832476; called by muse, mutect2, varscan2
- ZNF536 | c.1989G>T p.G663= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100834795; called by muse, mutect2
- ZNF536 | c.2308C>T p.L770= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs771068303, COSV100835334, COSV62828014; called by muse, mutect2, varscan2
- ZNF749 | c.1854G>A p.G618= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100494373; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826238 C>A | 3'Flank (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- CUBN | c.-1G>A | 5'UTR (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100910605; called by muse, mutect2, varscan2
- TTN | c.10360+5006G>A | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs764591972, COSV100617478, COSV60152921; called by muse, mutect2, varscan2
